CPTAC case 06BR003 — Breast — Ductal and Lobular Neoplasms (CPTAC-2)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Ductal and Lobular Neoplasms; Primary site: Breast.
https://portal.gdc.cancer.gov/cases/27e868aa-dbf2-42b3-889d-72f17787b965

Demographics
Sex at birth: female; Ethnicity: hispanic or latino.

Diagnoses (1)
1. Infiltrating duct carcinoma, NOS: ICD-O-3 morphology code: 8500/3; Tissue or organ of origin: Breast, NOS; Age at diagnosis: 74.9 years (27,374 days); AJCC pathologic stage: Stage IIA; Prior malignancy: no.

Biospecimens (3 samples)
- Samples 31b13596-554e-452f-91a4-7e67a8, 4f6b74fb-8b2e-40e2-87a5-02817e (2 with the same recorded description): Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
- Sample a51ad581-647d-4da3-8b7e-7641b8: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Preservation method: Frozen.
